Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6395, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6395-01A (Primary Tumor).

Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:

Final 1

Patient Name:

MRN:

Service Date/Time:

DOB/Age/Gender:

Male Provider:

Location: Responsible Staff:

PATH. NO:

NAME:

AGE/SEX: M DOB:

MED. REC. NO:

SURGERY DATE:

RECEIVE DATE:

PHYSICIAN:

UPDATED REPORT

- SEE ADDENDUM SPECIAL STAIN REPORT:

MIB-1 LABELLING INDEX 40%

PATHOLOGICAL DIAGNOSIS:

A AND B. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSIES: GLIOMA, HIGH HISTOLOGICAL GRADE (IV), WITH NECROSIS AND HYALINIZING VASCULOPATHY. SEE MICROSCOPY DESCRIPTION AND COMMENT.

SPECIAL STAIN REPORT: MIB-1 LABELLING INDEX 40%.

Operation/Specimen: Brain, left frontal.

Clinical History and Pre-Op Dx: year old man with history of a mixed glioma with atypical features biopsied in , recent onset seizure, and ? tumor recurrence.

GROSS PATHOLOGY: A. Received fresh, four fragments, 1 x 0.8 x 0.4 cm in aggregate. Soft, tannish-grey, focally hemorrhagic. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Frozen section diagnosis: Brain, left frontal: Malignant glioma.

B. Received fresh, three fragments, 1.0 cm in aggregate, soft, hemorrhagic. In total #3.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Brain, left frontal: Malignant glioma.

MICROSCOPIC: A. Portions of brain extensively infiltrated by a cellular neoplastic proliferation of glial cells with nuclear anaplasia, mitotic figures, focal necrosis and microvascular cellular proliferation. There also are vessels with thick hyalinized walls. In the smears, but also in the tissue, many cells have an oligodendroglial phenotype.

B. Portions of brain heavily infiltrated by a neoplasm similar to that described for part A. In here, however, there are extensive areas of coagulation necrosis and small vessels with prominent hyalinizing vasculopathy.

COMMENT: The lesion is a high histological grade (grade IV) glioma with extensive necrosis and hyalinizing vasculopathy. The neoplasm has Cont'd....

a focal oligodendroglial component. The vasculopathy and probably some necrosis are secondary to radiation. A MIB-I is requested and an addendum report will follow.

ADDENDUM REPORT:

A MIB-1 immunoperoxidase stain was performed on block #2.

A MIB-1 labelling index of 40% was determined in the more cellular areas.

TISSUE COMMITTEE CODE: TC1.

BILLING CODES:

OSCF ICD O-3
Glioblastoma, multiforme
path
Glioma, malignant
OSCF 9380/3
Site: Brain, supratentorial NO: C71.0
path
① Brain, frontal lobe C71.1
JWH/13

iw 7/31/17
4/9/2013

Source: NCI Genomic Data Commons file 3135724a-703d-419c-8a37-87779ca9dd82 (TCGA-DU-6395.06DC35CF-0317-47F4-9F85-AAD0768C40B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).